Somatic mutation profile of tumor specimen TCGA-A2-A0SY-01A (aliquot TCGA-A2-A0SY-01A-31D-A099-09) from TCGA case TCGA-A2-A0SY, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62.8 years (22,928 days).
Specimen TCGA-A2-A0SY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 016bf20c-8739-420e-a663-cefa0908d435.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0SY-10A (Blood Derived Normal), aliquot TCGA-A2-A0SY-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c3578de-1c8b-4bf6-9968-2e39cceb55ad

The open-access MAF lists 139 somatic variants for this specimen: 104 protein-altering or splice-affecting, 34 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 34, Nonsense Mutation 7, Frame Shift Del 2, Frame Shift Ins 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1459219194, COSV51645075; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 36/110 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA4 | c.2947A>T p.T983S | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.739); catalogued as CM099661, COSV64672659; called by muse, mutect2, varscan2
- ADAMTS2 | c.2917G>A p.E973K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.137); catalogued as rs766939294, COSV52371632; called by muse, mutect2, varscan2
- ADD1 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV53267988; called by muse, mutect2, varscan2
- ADGRE2 | c.153C>A p.F51L | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV59692792; called by muse, mutect2, varscan2
- AGO2 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55046503; called by muse, mutect2, varscan2
- ARG1 | c.486C>G p.F162L | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV51580861; called by muse, mutect2, varscan2
- ARHGEF10 | c.1621G>C p.E541Q (on ENST00000398564; = p.E516Q on NM_014629.4) | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs768961111, COSV50645711; called by muse, mutect2, varscan2
- ASPM | c.6551G>A p.R2184Q | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200848981, COSV99659617; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ATG5 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV58347290; called by muse, mutect2, varscan2
- ATP2B1 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.403); catalogued as COSV53806133; called by muse, mutect2, varscan2
- ATP6V0A2 | c.655G>C p.V219L | Missense Mutation (SNP) | VAF 64/269 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.038); catalogued as COSV57748605; called by muse, mutect2, varscan2
- C3 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 77/267 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55571280; called by muse, mutect2, varscan2
- CACNA1C | c.1258G>C p.D420H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59708735; called by muse, mutect2, varscan2
- CACNA1D | c.1900A>G p.T634A (on ENST00000350061 / NM_001128840.3; = p.T654A on NM_000720.4) | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV55443295; called by muse, mutect2, varscan2
- CACNG4 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs1230291904, COSV50924610; called by muse, mutect2, varscan2
- CHST2 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs868587203, COSV58885213; called by muse, mutect2, varscan2
- CMYA5 | c.12076G>C p.E4026Q | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.153); catalogued as COSV69745397; called by muse, mutect2, varscan2
- CTCFL | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753318139, COSV54772895; called by muse, mutect2, varscan2
- CWH43 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV56937827; called by muse, mutect2, varscan2
- DMRT1 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV66520663; called by muse, mutect2, varscan2
- DNAH5 | c.10927C>G p.L3643V | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV54217024; called by muse, mutect2, varscan2
- DNAH6 | c.1347G>C p.E449D | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV52855722; called by muse, mutect2, varscan2
- FKBP10 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 72/619 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as COSV54055359; called by muse, mutect2, varscan2
- FN1 | c.6968G>A p.G2323E (on ENST00000359671 / NM_001365524.2; = p.G2292E on NM_002026.4) | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383924390, COSV100116212; called by muse, mutect2
- FSTL5 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV60180406, COSV60188710; called by muse, mutect2, varscan2
- GDF9 | c.750G>C p.Q250H | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.553); catalogued as COSV51526064; called by muse, mutect2, varscan2
- GFRA2 | c.668C>A p.S223Y | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100151440; called by muse, mutect2, varscan2
- GPAT4 | c.934A>G p.K312E | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV67840586; called by muse, mutect2, varscan2
- HOMER2 | c.1000G>A p.D334N (on ENST00000304231 / NM_199330.3; = p.D323N on NM_004839.4) | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372825300; called by muse, mutect2, varscan2
- HPS1 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs780626717, COSV57267287; called by muse, mutect2, varscan2
- HRC | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.685); catalogued as COSV53255885; called by muse, mutect2, varscan2
- HRC | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 36/160 reads (23%) | catalogued as COSV53255893, COSV53256193; called by muse, mutect2, varscan2
- HSF1 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60047480; called by mutect2, varscan2
- IL3RA | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.132); catalogued as rs760003424, COSV58430733; called by muse, mutect2, varscan2
- KCND2 | c.1744G>C p.E582Q | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.322); catalogued as COSV58574029, COSV58575568; called by muse, mutect2, varscan2
- KIF1A | c.1049G>T p.R350L | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57486399; called by muse, mutect2, varscan2
- KIF5A | c.1905G>A p.Q635= | Splice Region (SNP) | VAF 27/82 reads (33%) | catalogued as COSV54053468; called by muse, mutect2, varscan2
- KLHL11 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59861772; called by muse, varscan2
- LAMA2 | c.6913G>C p.E2305Q | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70344197; called by muse, mutect2, varscan2
- LARP7 | c.782C>G p.S261C | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs771193812, COSV60520624; called by muse, mutect2, varscan2
- LRCH1 | c.1586G>C p.R529T | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as COSV60845988; called by muse, mutect2, varscan2
- LRCH2 | c.1511C>T p.T504I | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV57748719; called by muse, mutect2, varscan2
- LRRC27 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs138072740; called by muse, mutect2, varscan2
- LRRIQ1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV67828818; called by muse, mutect2, varscan2
- MAGI2 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1448739111, COSV62700633; called by muse, mutect2, varscan2
- MAST4 | c.976C>G p.H326D (on ENST00000403625 / NM_001164664.2; = p.H137D on NM_015183.3) | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55121373; called by muse, mutect2, varscan2
- MCF2L2 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs775278339, COSV61051831; called by muse, mutect2, varscan2
- MEGF6 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as COSV62992677; called by muse, mutect2
- METTL23 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV57971287; called by muse, mutect2, varscan2
- MINDY3 | c.840G>A p.W280* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | catalogued as rs753464168, COSV53219511; called by muse, mutect2, varscan2
- NCF2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV62315158; called by muse, mutect2, varscan2
- NHS | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as COSV66273517; called by muse, mutect2, varscan2
- NOX4 | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 47/151 reads (31%) | catalogued as COSV54450724; called by muse, mutect2, varscan2
- NPEPPS | c.1013C>G p.S338C | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751723632, COSV59101706; called by muse, mutect2, varscan2
- NQO2 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV57642685; called by muse, mutect2, varscan2
- NRP1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV55163699; called by muse, mutect2, varscan2
- OPRL1 | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1379555368, COSV61091336; called by muse, mutect2, varscan2
- OR14I1 | c.218C>G p.S73* | Nonsense Mutation (SNP) | VAF 44/205 reads (21%) | catalogued as COSV61199393; called by muse, mutect2, varscan2
- OR2B11 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV59509854; called by muse, mutect2, varscan2
- OR2G2 | c.540C>A p.F180L | Missense Mutation (SNP) | VAF 78/296 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV100189588, COSV60739959; called by muse, mutect2
- OTUD6A | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV57973003; called by muse, mutect2, varscan2
- PCDHGA11 | c.1226G>A p.R409K | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.01); catalogued as COSV53927067; called by muse, mutect2, varscan2
- PIK3CB | c.1491G>C p.E497D | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV56684898; called by muse, mutect2, varscan2
- PIM2 | c.915G>C p.L305F | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.69); catalogued as COSV55944299; called by muse, mutect2, varscan2
- PLXDC1 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 45/346 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); catalogued as rs779072478, COSV59550341; called by muse, mutect2, varscan2
- PPP1R27 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT tolerated (0.49); PolyPhen probably damaging (1); catalogued as COSV57672264; called by muse, mutect2, varscan2
- PPP1R3A | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52880236; called by muse, mutect2, varscan2
- PRMT9 | c.2080C>T p.Q694* | Nonsense Mutation (SNP) | VAF 31/130 reads (24%) | catalogued as rs1397695069, COSV59359385; called by muse, mutect2, varscan2
- PRRC2C | c.6491C>G p.S2164* (on ENST00000367742; = p.S2162* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 21/94 reads (22%) | catalogued as COSV58903692; called by muse, mutect2, varscan2
- RAB37 | c.350C>G p.S117C (on ENST00000392613 / NM_001006638.3; = p.S110C on NM_175738.5) | Missense Mutation (SNP) | VAF 77/225 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100462443, COSV61193698; called by muse, mutect2, varscan2
- RARB | c.205G>C p.E69Q (on ENST00000383772 / NM_001290216.2; = p.E62Q on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/242 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV58066394; called by muse, mutect2, varscan2
- RBFOX1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1174108648, COSV100299392; called by muse, mutect2
- RIMBP3 | c.3218C>T p.S1073F | Missense Mutation (SNP) | VAF 38/367 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747934855; called by muse, mutect2
- RNF121 | c.804G>C p.K268N | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52620424; called by muse, mutect2, varscan2
- SH3PXD2B | c.960G>C p.Q320H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); catalogued as COSV100287521, COSV100287685; called by muse, mutect2, varscan2
- SHANK1 | c.543G>C p.K181N | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53248208, COSV99520291; called by muse, mutect2, varscan2
- SINHCAF | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV61797191; called by muse, mutect2, varscan2
- SLK | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59824723; called by muse, varscan2
- SLK | c.3298C>G p.Q1100E | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.954); catalogued as COSV59824730; called by muse, varscan2
- SMARCA1 | c.1384C>G p.H462D | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV64411510, COSV64413378; called by muse, mutect2, varscan2
- SMC5 | c.1476A>T p.K492N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100746971; called by muse, mutect2
- SNX13 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1031788455, COSV68063873; called by muse, mutect2, varscan2
- SPICE1 | c.1852C>G p.Q618E | Missense Mutation (SNP) | VAF 105/299 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV55619730; called by muse, mutect2, varscan2
- TAB3 | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.106); catalogued as COSV55835778; called by muse, mutect2, varscan2
- TAF1L | c.1660C>G p.L554V | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV54260347; called by muse, mutect2, varscan2
- TCP11L2 | c.1302C>G p.I434M | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54429580; called by muse, mutect2, varscan2
- TGDS | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54300440; called by muse, mutect2, varscan2
- TGM4 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.018); catalogued as rs759273340, COSV56093437; called by muse, mutect2, varscan2
- THAP7 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as COSV53146639; called by muse, mutect2, varscan2
- TINAG | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV52508079; called by muse, mutect2, varscan2
- TOMM20L | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as COSV53621410; called by muse, mutect2, varscan2
- TPCN1 | c.2257C>T p.H753Y | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV59234216; called by muse, mutect2, varscan2
- TRAF3IP3 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50551830, COSV99160688; called by muse, mutect2, varscan2
- TTN | c.30067G>C p.E10023Q (on ENST00000591111; = p.E9096Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/469 reads (32%) | PolyPhen probably damaging (0.979); catalogued as COSV59982649; called by muse, mutect2, varscan2
- UMPS | c.894G>C p.L298F | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV51736772; called by muse, mutect2, varscan2
- WDR33 | c.2603C>G p.S868C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.253); catalogued as COSV59247742; called by muse, mutect2, varscan2
- ZNF567 | c.1621T>A p.S541T (on ENST00000536254 / NM_001322913.1; = p.S510T on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62444840; called by muse, mutect2, varscan2
- CDH1 | c.53_54insAC p.S19Pfs*38 | Frame Shift Ins (INS) | VAF 9/20 reads (45%) | called by mutect2, pindel, varscan2
- GPS2 | c.310del p.E104Nfs*5 | Frame Shift Del (DEL) | VAF 120/326 reads (37%) | called by mutect2, pindel, varscan2
- IGHV1-45 | c.96G>C p.K32N | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MYB | c.812_825del p.N271Sfs*10 | Frame Shift Del (DEL) | VAF 92/368 reads (25%) | called by mutect2, pindel, varscan2
- SCAF4 | c.3431_3432dup p.A1145Rfs*10 | Frame Shift Ins (INS) | VAF 24/83 reads (29%) | called by mutect2, pindel, varscan2
- ACCSL | c.144G>A p.T48= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs771264543, COSV66580843; called by muse, mutect2, varscan2
- ACTN2 | c.2442C>T p.F814= | Silent (SNP) | VAF 49/234 reads (21%) | catalogued as rs1803031, COSV100856541; called by muse, mutect2, varscan2
- AFF4 | c.345C>T p.P115= | Silent (SNP) | VAF 177/389 reads (46%) | catalogued as COSV54793448, COSV99534543; called by muse, mutect2, varscan2
- AMER1 | c.3231T>C p.P1077= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV57658568; called by muse, mutect2, varscan2
- ANKLE2 | c.2176C>T p.L726= | Silent (SNP) | VAF 13/164 reads (8%) | catalogued as COSV100513948; called by muse, mutect2
- APOB | c.2271T>C p.S757= | Silent (SNP) | VAF 28/125 reads (22%) | catalogued as COSV51931185; called by muse, mutect2, varscan2
- ARHGAP24 | c.1857A>T p.R619= (on ENST00000395184 / NM_001025616.3; = p.R526= on NM_031305.3) | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV51988179; called by muse, mutect2, varscan2
- BROX | c.174G>A p.K58= | Silent (SNP) | VAF 63/298 reads (21%) | catalogued as COSV61799136, COSV61799224; called by muse, mutect2, varscan2
- CATSPERD | c.84G>A p.V28= | Silent (SNP) | VAF 53/194 reads (27%) | catalogued as COSV62261255; called by muse, mutect2, varscan2
- CDH12 | c.810C>T p.P270= | Silent (SNP) | VAF 12/269 reads (4%) | catalogued as COSV101201497, COSV66438116; called by muse, mutect2
- DDX3X | c.480G>A p.E160= (on ENST00000399959; = p.E161= on NM_001356.5) | Silent (SNP) | VAF 56/171 reads (33%) | catalogued as COSV67863378; called by muse, mutect2, varscan2
- DNAJB13 | c.420C>G p.V140= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV100334438, COSV60269698; called by muse, mutect2, varscan2
- FAT1 | c.10494G>A p.L3498= | Silent (SNP) | VAF 6/146 reads (4%) | catalogued as COSV101499098; called by muse, mutect2
- FLII | c.666G>A p.L222= | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as COSV58944407; called by muse, mutect2, varscan2
- GRM2 | c.249C>T p.R83= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV56583970; called by muse, mutect2, varscan2
- ITGA10 | c.2721C>A p.V907= | Silent (SNP) | VAF 39/173 reads (23%) | catalogued as COSV65196702; called by muse, mutect2, varscan2
- KCNV2 | c.1542G>A p.E514= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as COSV66055862, COSV66056309; called by muse, mutect2, varscan2
- LCOR | c.1911A>C p.S637= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV53715292; called by muse, mutect2, varscan2
- LPL | c.1221C>G p.L407= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as COSV60930815; called by muse, mutect2, varscan2
- MROH1 | c.1060C>T p.L354= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV58188781; called by muse, mutect2, varscan2
- MS4A13 | c.288C>T p.Y96= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs142250716; called by muse, mutect2, varscan2
- MTR | c.921C>T p.H307= | Silent (SNP) | VAF 36/152 reads (24%) | catalogued as COSV63967554; called by muse, mutect2, varscan2
- OR4F15 | c.198C>G p.L66= | Silent (SNP) | VAF 34/258 reads (13%) | catalogued as COSV59968654, COSV59968717; called by muse, mutect2, varscan2
- PLK3 | c.1719C>T p.L573= | Silent (SNP) | VAF 53/197 reads (27%) | catalogued as COSV59499560; called by muse, mutect2, varscan2
- PLK3 | c.1899C>G p.L633= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV59499563; called by muse, mutect2, varscan2
- SCN1A | c.5541C>G p.L1847= (on ENST00000303395 / NM_001202435.3; = p.L1836= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/138 reads (24%) | catalogued as COSV57666085; called by muse, mutect2, varscan2
- SEC24B | c.3057C>T p.I1019= | Silent (SNP) | VAF 57/176 reads (32%) | catalogued as COSV54497555; called by muse, mutect2, varscan2
- SMPD1 | c.189T>G p.P63= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV54967435; called by muse, mutect2, varscan2
- SRP72 | c.1287C>T p.F429= | Silent (SNP) | VAF 64/189 reads (34%) | catalogued as COSV61377358; called by muse, mutect2, varscan2
- SRSF1 | c.174C>T p.F58= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV51964700; called by muse, mutect2, varscan2
- STAT5B | c.1149C>G p.L383= | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as COSV53181722; called by muse, mutect2, varscan2
- THOC2 | c.747G>A p.G249= | Silent (SNP) | VAF 47/177 reads (27%) | catalogued as rs909315652, COSV55543936; called by muse, mutect2, varscan2
- TRIM25 | c.522C>T p.C174= | Silent (SNP) | VAF 30/52 reads (58%) | catalogued as COSV57543774; called by muse, mutect2, varscan2
- TRPM4 | c.486C>T p.I162= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as rs140412103; called by muse, mutect2, varscan2
- PAX3 | c.586+425C>T | Intron (SNP) | VAF 18/60 reads (30%) | catalogued as rs372706630; called by muse, mutect2, varscan2
